Surgical pathology report (de-identified scan), TCGA case TCGA-34-5234, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-5234-01A (Primary Tumor).

TCGA-34-5234

FINAL DIAGNOSIS:

Summary Statement

The left upper lobè lingulectomy demonstrates a 2.0 cm moderately differentiated squamous cell carcinoma with angiolymphatic invasion but without visceral pleural invasion, with all margins free and no lymph node metastases. Pathologic stage T1, N0, MX.

PART 1: BRONCHUS, LEFT SECONDARY CARINA, BIOPSY –
FRAGMENTS OF BRONCHIAL MUCOSA WITH NO SIGNIFICANT ABNORMALITY.

PART 2: LYMPH NODE, LEVEL 9 LYMPH NODE, BIOPSY –
SOLITARY LYMPH NODE WITH NO SIGNIFICANT ABNORMALITY.

PART 3: LYMPH NODE, LEVEL 10 LYMPH NODE, BIOPSY –
THREE FRAGMENTS OF LYMPH NODE WITH ANTHRACOSILICOTIC NODULES. NO EVIDENCE OF
MALIGNANCY.

PART 4: LUNG, LINGULAR SEGMENT OF LEFT UPPER LOBE, SEGMENTECTOMY –
A. MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA WITH PROMINENT LEPIDIC GROWTH
AND FOCAL ANGIOLYMPHATIC INVASION. DIAMETER 2.0 CM. NO EVIDENCE OF VISCERAL PLEURAL
INVASION. ALL MARGINS FREE. MODERATE HOST LYMPHOCYTIC RESPONSE. PATHOLOGIC STAGE T1,
N0, MX.
B. RESPIRATORY BRONCHIOLITIS WITH EMPHYSEMATOUS CHANGE.

PART 5: LYMPH NODES, LEVEL 5 LYMPH NODE, BIOPSY –
SEVEN FRAGMENTS OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.

PART 6: LYMPH NODES, LEVEL 11 LYMPH NODE, BIOPSY –
TWO FRAGMENTS OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.

COMMENT:

The squamous cell carcinoma is a moderately differentiated keratinizing squamous carcinoma with a marked desmoplastic reaction. Of interest is the prominent lepidic growth by the neoplastic squamous cells, which is associated with metaplasia of bronchiolar epithellum and alveolar pneumocytes, with pagetoid spread.

Source: NCI Genomic Data Commons file 85d0bd6c-dc31-4089-9d35-1bc2fe252a6e (TCGA-34-5234.ECDE2410-DC20-4F6D-9215-4BF5452D530C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).